CDDP_EAGLE case CDDP-ACR2 — CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/5ac87e01-90cb-4394-a137-2bbdb15fbd75

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Year of birth: 1923; Vital status: Dead; Days to death: 2,074 days (5.7 years); Year of death: 2007; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.12; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Age at diagnosis: 79 years; Year of diagnosis: 2002; Days to diagnosis: 0 days; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Last known disease status: With tumor; Days to last follow up: 2,074 days (5.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Exposures
- Pack years smoked: 0; Cigarettes per day: 0.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CDDP-ACR2-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample CDDP-ACR2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CDDP-ACR2-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 4; Percent necrosis: 1; Percent stromal cells: 25; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Protocol status: Completed; Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); Cause of death: Submitted Malignancy and/or related tumor event; Height cm at diagnosis: 150 cm; Weight kg at diagnosis: 55 kg; History neoadjuvant treatment: No; Tobacco smoking history indicator: 1; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Followup history list, Followup history: Tumor status: Never Tumor Free.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other Surgical Resection (Please Specify).
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
